MMRF case MMRF_1841 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ca5502c3-1fcb-411d-a1f0-f04280324ed9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.3 years (22,390 days); ISS stage: II; Days to last known disease status: 1,082 days (3.0 years); Days to last follow up: 1,082 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 113 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 179 days; Days to treatment end: 179 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 439 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 1): M Protein 2.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.51 mg/dL; Immunoglobulin G 29.1 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.75 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 10.9 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 370 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 29 g/L; Total Protein 8.7 g/dL; Glucose 6.27 mmol/L; C-Reactive Protein 1.87 mg/dL.
- Day 85: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Hemoglobin 8.18 mmol/L; Leukocytes 14.9 ×10⁹/L; Absolute Neutrophil 10.9 ×10⁹/L; Platelets 429 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 40.8 g/L; Total Protein 7.3 g/dL; Glucose 8.91 mmol/L.
- Day 162 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 4.32 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.91 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 332 ×10⁹/L; Creatinine 40.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.1 mmol/L; Albumin 31 g/L; Total Protein 6 g/dL; Glucose 5.67 mmol/L.
- Day 260 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 5.89 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 6.2 g/dL; Glucose 6.88 mmol/L.
- Day 358 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 6.08 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 3.93 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 302 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 8.09 mmol/L.
- Day 442: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 4.92 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.46 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 75 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 1.98 mmol/L; Albumin 31 g/L; Total Protein 6 g/dL; Glucose 8.09 mmol/L.
- Day 512: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.58 mg/dL; Immunoglobulin G 6.74 g/L; Immunoglobulin A 2.22 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 5.15 mmol/L; Leukocytes 1.9 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 49 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 6.3 g/dL; Glucose 7.1 mmol/L.
- Day 632 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.19 mg/dL; Immunoglobulin G 8.06 g/L; Immunoglobulin A 2.12 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.9 g/dL; Glucose 7.87 mmol/L.
- Day 716: Hemoglobin 6.57 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 7.59 mmol/L.
- Day 815 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.55 mg/dL; Immunoglobulin G 8.61 g/L; Immunoglobulin A 2.15 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 35.3 g/L; Total Protein 6.6 g/dL; Glucose 10.1 mmol/L.
- Day 878 (ECOG 1): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.67 mg/dL; Immunoglobulin G 8.85 g/L; Immunoglobulin A 2.05 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 5.77 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 82 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 32 g/L; Total Protein 6.7 g/dL; Glucose 9.41 mmol/L.
- Day 990 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.29 mg/dL; Immunoglobulin G 9.69 g/L; Immunoglobulin A 2.27 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 76 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.08 mmol/L; Albumin 34 g/L; Total Protein 6.5 g/dL; Glucose 8.69 mmol/L.
- Day 1,082: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.64 mg/dL; Immunoglobulin G 9.61 g/L; Immunoglobulin A 2.52 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 7.7 mmol/L.

Other clinical attributes
- Day -12: Weight: 81 kg; Height: 160 cm.

Biospecimens (2 samples)
- Sample MMRF_1841_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1841_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
